Somatic mutation profile of tumor specimen TCGA-CG-4301-01A (aliquot TCGA-CG-4301-01A-01D-1158-08) from TCGA case TCGA-CG-4301, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.3 years (27,516 days).
Specimen TCGA-CG-4301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb868c3-8568-4d3e-b3b8-afe42206b37b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4301-10A (Blood Derived Normal), aliquot TCGA-CG-4301-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec244615-686f-46d9-9ad9-a111dc26b770

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 4, Splice Region 2, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8668C>G p.L2890V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587779874, COSV53724786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50993979; called by muse, mutect2, varscan2
- ABCC11 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139034695, COSV62324823; called by muse, varscan2
- ARMC2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV64550529, COSV64553671; called by muse, varscan2
- ATP5F1B | c.1295A>G p.K432R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as rs745377010, COSV51641233; called by muse, mutect2, varscan2
- BAIAP2 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.779); catalogued as rs1425310031, COSV58338918; called by muse, mutect2, varscan2
- C1QTNF1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs537928727, COSV59263348; called by muse, mutect2, varscan2
- CCDC22 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66051465, COSV66051824; called by muse, mutect2, varscan2
- CUBN | c.979A>T p.T327S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64723403; called by muse, mutect2, varscan2
- DCC | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV59123957; called by muse, mutect2
- DDA1 | c.84G>A p.S28= | Splice Region (SNP) | VAF 21/123 reads (17%) | catalogued as rs976859501, COSV63289986; called by muse, mutect2, varscan2
- ELF4 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 16/201 reads (8%) | catalogued as COSV57454201; called by muse, mutect2
- EML4 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100581149; called by muse, mutect2, varscan2
- EPB41L3 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 84/369 reads (23%) | catalogued as rs781377051, CM1213159, COSV59463637; called by muse, mutect2, varscan2
- FAM166A | c.253T>A p.Y85N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV61118410; called by muse, mutect2, varscan2
- FCRL3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as rs759624449, COSV63843896; called by muse, mutect2, varscan2
- GOLGA4 | c.6068C>G p.A2023G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62712774; called by muse, mutect2, varscan2
- GSPT2 | c.879T>G p.S293R | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61214809; called by muse, mutect2, varscan2
- HCN4 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420807618, COSV56082015; called by muse, mutect2, varscan2
- HIP1 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs782630208, COSV61189744; called by muse, mutect2, varscan2
- IL23A | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.423); catalogued as COSV57336279; called by muse, mutect2, varscan2
- LRP2 | c.11195G>A p.C3732Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217662405, COSV55567049; called by muse, mutect2, varscan2
- MYLK | c.4617G>A p.E1539= | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as COSV60618012; called by muse, mutect2, varscan2
- NBEA | c.4968A>C p.E1656D | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.108); catalogued as COSV59809848; called by muse, mutect2
- NLRX1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV52707700; called by muse, mutect2, varscan2
- P4HA2 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as rs201861932; called by muse, mutect2, varscan2
- PHF24 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs189099874, COSV54275646; called by muse, mutect2, varscan2
- PNPLA6 | c.3703G>A p.D1235N (on ENST00000414982 / NM_001166111.2; = p.D1187N on NM_006702.5) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55382871; called by muse, mutect2, varscan2
- PPP2R1B | c.1640A>T p.N547I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59536921; called by muse, mutect2, varscan2
- PTPRS | c.3700C>T p.R1234W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs866165812, COSV53634153; called by mutect2, varscan2
- RABGAP1L | c.2386A>G p.M796V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs891639173, COSV52315818; called by muse, mutect2, varscan2
- RASA1 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV57199736; called by muse, mutect2, varscan2
- ROCK1 | c.3319C>G p.P1107A | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.07); catalogued as COSV67698198; called by muse, mutect2, varscan2
- SMYD3 | c.1181G>C p.R394T (on ENST00000490107 / NM_001375962.1; = p.R335T on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV63628727; called by muse, mutect2, varscan2
- SNIP1 | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV56167844; called by muse, mutect2, varscan2
- SP3 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 38/516 reads (7%) | catalogued as COSV59466260; called by muse, mutect2
- TUBA3C | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as rs139914455, COSV67139666; called by muse, mutect2, varscan2
- UBC | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60060739; called by muse, mutect2, varscan2
- VIRMA | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV52589246; called by mutect2, varscan2
- ZNF513 | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV52009515; called by muse, mutect2, varscan2
- ZNF804B | c.2063T>C p.V688A | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs767498932, COSV60844915; called by muse, mutect2, varscan2
- SKAP2 | c.343_347del p.P115Cfs*8 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- UBA1 | c.812-8_812-1del p.X271_splice | Splice Site (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- BRD4 | c.330A>T p.I110= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV54591825; called by muse, mutect2, varscan2
- C20orf85 | c.225G>A p.P75= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs568065621, COSV64519782; called by muse, mutect2, varscan2
- FGF21 | c.288C>A p.V96= | Silent (SNP) | VAF 31/303 reads (10%) | catalogued as COSV55810967; called by muse, mutect2, varscan2
- GDF10 | c.192C>T p.A64= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs990386827; called by muse, mutect2
- JMY | c.1551A>G p.T517= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV68661856; called by muse, mutect2
- NALCN | c.1116C>T p.R372= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs200582234, COSV51943338; called by muse, mutect2, varscan2
- PCDHA11 | c.2154G>A p.T718= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs374337862, COSV56514749; called by muse, mutect2, varscan2
- SCUBE3 | c.1260C>A p.G420= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV51459349; called by muse, mutect2, varscan2
- TERT | c.2370C>T p.V790= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs376251639; called by muse, mutect2, varscan2
- WHRN | c.690C>T p.T230= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs779112096, COSV54333665; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GP6 | c.*467C>T | 3'UTR (SNP) | VAF 28/142 reads (20%) | catalogued as COSV100117690; called by muse, mutect2, varscan2
